Gene-level copy-number profile of tumor specimen ALCH-B2R2-TTP1-A from ALCHEMIST case ALCH-B2R2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,250 days).
Specimen ALCH-B2R2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ccd4d36f-80ef-45b1-9b1e-21edd18a2e9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2R2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,759 have no estimate.
https://portal.gdc.cancer.gov/files/4387084b-144e-4de9-beee-f3c1ee5e166f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,464; copy number 2: 52,253; copy number 3: 2,877; copy number 4: 249; copy number 5: 16; copy number 6: 1; copy number 7: 1; copy number 9: 2; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,453,927–43,456,995, 1 gene, copy number 5 (within-gene range 3–5): HYI-AS1.
- chr1:149,345,661–149,556,361, 4 genes, copy number 5: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr5:1,544,107–1,551,710, 1 gene, copy number 6: AC091849.2.
- chr5:179,793,980–179,796,647, 1 gene, copy number 7 (within-gene range 4–7): LTC4S.
- chr9:40,223,285–40,293,955, 4 genes, copy number 5–9: ANKRD20A2P, RNU6-1269P, BX664727.2, SNX18P8.
- chr9:40,481,558–40,642,117, 6 genes, copy number 5: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.
- chr10:5,498,697–5,499,570, 1 gene, copy number 5: CALML5.
- chr16:11,926,199–11,926,307, 1 gene, copy number 5: AC007216.5.
- chr17:18,476,737–18,494,945, 1 gene, copy number 10: LGALS9C.
- chr19:1,021,522–1,021,628, 1 gene, copy number 5: RNU6-2.

Autosomal genes at a single copy (total copy number 1): 608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
